Somatic mutation profile of tumor specimen TCGA-CN-4731-01A (aliquot TCGA-CN-4731-01A-01D-1434-08) from TCGA case TCGA-CN-4731, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 63.5 years (23,194 days).
Specimen TCGA-CN-4731-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f4bba68-b6bc-47ae-8268-e21cd00eb0f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4731-10A (Blood Derived Normal), aliquot TCGA-CN-4731-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/323eb344-5412-4447-b7be-dabfe0751b32

The open-access MAF lists 123 somatic variants for this specimen: 85 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 34, Nonsense Mutation 10, Frame Shift Del 6, Splice Region 3, Intron 3, Splice Site 3, Frame Shift Ins 2, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 28/59 reads (47%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 72/123 reads (59%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.992T>A p.L331H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99771518; called by muse, mutect2, varscan2
- ABCC8 | c.3368G>T p.R1123I | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100216427, COSV100217419; called by muse, mutect2, varscan2
- ACSM2B | c.658T>C p.F220L | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100312844, COSV61657327; called by muse, mutect2, varscan2
- ACVR1B | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 48/81 reads (59%) | catalogued as COSV57777696; called by muse, mutect2, varscan2
- ALPL | c.799C>G p.H267D | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV100876247; called by muse, mutect2, varscan2
- ANK2 | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 44/141 reads (31%) | catalogued as COSV100002399, COSV52143804; called by muse, mutect2, varscan2
- API5 | c.617C>A p.T206K | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101124552; called by muse, mutect2, varscan2
- ATMIN | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as rs139034682; called by muse, mutect2, varscan2
- BARD1 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as COSV99638962; called by muse, mutect2, varscan2
- CACNA1A | c.6203C>G p.S2068C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100802694; called by muse, mutect2
- CNOT10 | c.337T>A p.Y113N | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); catalogued as COSV100094640, COSV59395466; called by muse, mutect2, varscan2
- COL1A1 | c.3880G>A p.E1294K | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99867526; called by muse, mutect2, varscan2
- CSF2RB | c.442T>A p.F148I | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV99454034; called by muse, mutect2, varscan2
- DBI | c.176G>A p.W59* (on ENST00000355857 / NM_001079862.3; = p.W76* on NM_020548.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100275957; called by muse, mutect2, varscan2
- DDX43 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946326, COSV64836667; called by muse, mutect2, varscan2
- DNAJC13 | c.4144C>T p.R1382C | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1026574542; called by muse, mutect2, varscan2
- EPB41L3 | c.2547G>C p.E849D | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.103); catalogued as COSV100549549; called by muse, mutect2, varscan2
- FMN1 | c.2957A>G p.Y986C (on ENST00000616417 / NM_001277313.2; = p.Y763C on NM_001103184.4) | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100568909; called by muse, mutect2, varscan2
- FREM2 | c.3191G>T p.S1064I | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99749298; called by muse, mutect2, varscan2
- FTSJ3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1567751138, COSV100834965; called by muse, mutect2, varscan2
- GDA | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs932604407, COSV52993612; called by muse, mutect2, varscan2
- GRB14 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55735674, COSV99814165; called by muse, mutect2, varscan2
- GRXCR2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100939998; called by muse, mutect2, varscan2
- GYS2 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 124/408 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748945649, COSV53926734; called by muse, mutect2, varscan2
- HIF1A | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1414586940, COSV100049023; called by muse, mutect2, varscan2
- HPS1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753635327, COSV57268666; called by muse, mutect2, varscan2
- IRX2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV100121767; called by muse, mutect2, varscan2
- ISM1 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99339845, COSV99339992; called by muse, mutect2, varscan2
- KCNMB4 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 71/97 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs780176319, COSV50690652; called by muse, mutect2, varscan2
- KCTD13 | c.504G>A p.K168= | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100442168; called by muse, mutect2, varscan2
- KRT5 | c.1164G>C p.E388D | Missense Mutation (SNP) | VAF 189/293 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV99358089; called by muse, mutect2, varscan2
- L2HGDH | c.739-2A>C p.X247_splice | Splice Site (SNP) | VAF 163/238 reads (68%) | catalogued as CS043123, COSV99910377; called by muse, mutect2, varscan2
- LRRC37A3 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs779068077, COSV100141134; called by muse, mutect2, varscan2
- LRRN2 | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100912893; called by muse, mutect2, varscan2
- MAT2A | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99290019; called by muse, mutect2, varscan2
- MCM4 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100031626; called by muse, mutect2
- MYEOV | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100456675, COSV100456746; called by muse, mutect2, varscan2
- MYH8 | c.5627C>T p.A1876V | Missense Mutation (SNP) | VAF 132/456 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs200825271; called by muse, mutect2, varscan2
- NCAPD2 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100217284; called by muse, mutect2, varscan2
- NCR1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs781384445, COSV52558289; called by muse, mutect2, varscan2
- NDUFV1 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1176578496, COSV100295351; called by muse, mutect2, varscan2
- NLRC3 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100072956; called by muse, mutect2, varscan2
- NRXN1 | c.3493T>A p.L1165M | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV100455644; called by muse, varscan2
- OSTN | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV100174256; called by muse, mutect2
- PDZD11 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV99333731; called by muse, mutect2, varscan2
- PGBD1 | c.1730A>T p.Q577L | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV99460520; called by muse, mutect2, varscan2
- PGP | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as COSV100063711; called by muse, mutect2, varscan2
- PLA2R1 | c.1962G>T p.E654D | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.169); catalogued as COSV99323082; called by muse, mutect2, varscan2
- PLD1 | c.1397A>G p.K466R | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100578375; called by muse, mutect2, varscan2
- PPP2R3A | c.2629C>A p.Q877K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs771624469, COSV99387528; called by muse, mutect2, varscan2
- PPT1 | c.750A>T p.Q250H (on ENST00000433473; = p.Q251H on NM_000310.4) | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100472470; called by muse, mutect2
- RAPGEF6 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV99726868; called by muse, mutect2, varscan2
- RIOK3 | c.929T>A p.F310Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100259368; called by muse, mutect2, varscan2
- RNF17 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV99693573; called by muse, mutect2, varscan2
- RP1 | c.3371C>A p.S1124* | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | catalogued as COSV55111051, COSV99607912; called by muse, mutect2, varscan2
- SERPINA4 | c.677C>G p.S226* | Nonsense Mutation (SNP) | VAF 44/157 reads (28%) | catalogued as rs1392033499, COSV100096821, COSV100097273; called by muse, mutect2, varscan2
- SETX | c.6766G>C p.V2256L | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99810161; called by muse, mutect2, varscan2
- SLC8A3 | c.2266G>C p.A756P (on ENST00000381269 / NM_183002.3; = p.A754P on NM_033262.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99385642; called by muse, mutect2, varscan2
- SPECC1 | c.1721C>T p.T574M | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs761861967, COSV54960999; called by muse, mutect2, varscan2
- ST8SIA3 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 62/225 reads (28%) | PolyPhen probably damaging (1); catalogued as COSV100129574; called by muse, mutect2, varscan2
- TADA2B | c.789C>G p.Y263* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99380681; called by muse, mutect2, varscan2
- TEKT4 | c.512T>A p.I171N | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1254796676, COSV99726463; called by muse, mutect2, varscan2
- TIE1 | c.2789G>A p.R930Q | Missense Mutation (SNP) | VAF 200/599 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781320560, COSV100992105; called by muse, mutect2, varscan2
- TTLL9 | c.321G>T p.L107= | Splice Region (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100206904; called by muse, mutect2, varscan2
- TULP1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201496818, COSV100004240; called by muse, mutect2, varscan2
- VPS13B | c.4820+2T>A p.X1607_splice | Splice Site (SNP) | VAF 74/181 reads (41%) | catalogued as CS090663, COSV100662406; called by muse, mutect2, varscan2
- VWCE | c.1524C>G p.Y508* | Nonsense Mutation (SNP) | VAF 35/204 reads (17%) | catalogued as COSV100075964, COSV57112041; called by muse, mutect2, varscan2
- WWOX | c.73A>T p.R25* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100880477; called by muse, mutect2, varscan2
- XIRP2 | c.187T>A p.F63I (on ENST00000628543; = p.F238I on NM_152381.6) | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.937); catalogued as COSV99744316; called by muse, mutect2, varscan2
- ZDHHC11 | c.1182G>A p.G394= | Splice Region (SNP) | VAF 34/221 reads (15%) | catalogued as COSV99363085; called by muse, mutect2, varscan2
- ZFP36L2 | c.641_642insA p.F214Lfs*260 | Frame Shift Ins (INS) | VAF 9/23 reads (39%) | catalogued as COSV99143922; called by mutect2, varscan2
- ZFYVE28 | c.2451C>A p.D817E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52119117; called by muse, mutect2, varscan2
- ZG16B | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs377483530, COSV66525609; called by muse, mutect2, varscan2
- ZNF546 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100713487, COSV61257359; called by muse, mutect2, varscan2
- CFAP157 | c.1488del p.E497Rfs*8 | Frame Shift Del (DEL) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- EEF1A2 | c.514_519delinsC p.K172Rfs*26 | Frame Shift Del (DEL) | VAF 23/160 reads (14%) | called by pindel, varscan2*
- FAM120C | c.442_459del p.G148_L153del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- FAT1 | c.4664del p.T1555Rfs*30 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- FAT1 | c.4029dup p.E1344* | Frame Shift Ins (INS) | VAF 34/116 reads (29%) | called by mutect2, pindel, varscan2
- FAT2 | c.6306del p.N2102Kfs*35 | Frame Shift Del (DEL) | VAF 75/188 reads (40%) | called by mutect2, pindel, varscan2
- LRRC40 | c.1658del p.D553Afs*13 | Frame Shift Del (DEL) | VAF 116/423 reads (27%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.423_425del p.D141del | In Frame Del (DEL) | VAF 54/146 reads (37%) | called by pindel, varscan2
- ZNF549 | c.529_530del p.L177Vfs*11 (on ENST00000376233 / NM_001199295.2; = p.L164Vfs*11 on NM_153263.2) | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by pindel, varscan2
- ABHD8 | c.399C>T p.P133= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs759388755, COSV53113287; called by muse, mutect2, varscan2
- ADAD1 | c.489A>G p.L163= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV99635852; called by muse, mutect2, varscan2
- ADAMTS12 | c.3930C>T p.N1310= | Silent (SNP) | VAF 77/489 reads (16%) | catalogued as rs141717162; called by muse, mutect2, varscan2
- ARL14 | c.408C>T p.I136= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as COSV100296501; called by muse, mutect2, varscan2
- BCAS3 | c.1860C>A p.G620= (on ENST00000390652 / NM_001353144.2; = p.G605= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 260/376 reads (69%) | catalogued as COSV101176235; called by muse, mutect2, varscan2
- CCAR1 | c.2364A>G p.K788= | Silent (SNP) | VAF 55/182 reads (30%) | catalogued as COSV99771149; called by muse, mutect2, varscan2
- CDH15 | c.1305C>T p.H435= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs191491461, COSV99228566; called by muse, mutect2, varscan2
- CLK2 | c.69G>A p.R23= | Silent (SNP) | VAF 65/222 reads (29%) | catalogued as COSV100751886, COSV62876977; called by muse, mutect2, varscan2
- CSTF2T | c.186C>T p.C62= | Silent (SNP) | VAF 81/256 reads (32%) | catalogued as COSV100484247; called by muse, mutect2, varscan2
- DNAH2 | c.12312C>T p.G4104= | Silent (SNP) | VAF 183/647 reads (28%) | catalogued as COSV101209464; called by muse, mutect2, varscan2
- DTX3L | c.663T>A p.S221= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV99950068; called by muse, mutect2, varscan2
- H1-2 | c.288G>C p.T96= | Silent (SNP) | VAF 53/318 reads (17%) | catalogued as COSV100642234, COSV59190483; called by muse, mutect2, varscan2
- ITGAM | c.1722C>A p.G574= (on ENST00000648685 / NM_001145808.2; = p.G573= on NM_000632.4) | Silent (SNP) | VAF 115/410 reads (28%) | catalogued as COSV99792631; called by muse, mutect2, varscan2
- KCNS1 | c.576G>A p.A192= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100067349; called by muse, mutect2
- LAMA2 | c.4626C>T p.V1542= | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as rs748160882, COSV101370594; called by muse, mutect2, varscan2
- LARGE1 | c.390G>T p.P130= | Silent (SNP) | VAF 70/280 reads (25%) | catalogued as COSV100504504; called by muse, mutect2, varscan2
- LIMD1 | c.582A>G p.P194= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV99837013; called by muse, mutect2, varscan2
- LRP1 | c.4356C>T p.D1452= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs771290632, COSV54502876; called by muse, mutect2, varscan2
- MED30 | c.468G>A p.L156= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99816080; called by muse, mutect2, varscan2
- MPRIP | c.2730A>G p.E910= | Silent (SNP) | VAF 85/295 reads (29%) | catalogued as COSV100505901; called by muse, mutect2, varscan2
- NLGN1 | c.741C>T p.F247= | Silent (SNP) | VAF 52/261 reads (20%) | catalogued as rs761909514, COSV100849216, COSV100849520, COSV64346935; called by muse, mutect2, varscan2
- NOC2L | c.534A>T p.R178= | Silent (SNP) | VAF 81/121 reads (67%) | catalogued as COSV100498069; called by muse, mutect2, varscan2
- OR2W3 | c.339G>T p.L113= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as COSV64456978; called by muse, mutect2, varscan2
- OR5T1 | c.795G>C p.G265= | Silent (SNP) | VAF 224/486 reads (46%) | catalogued as COSV100479100; called by muse, mutect2, varscan2
- OTOF | c.807G>A p.L269= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as rs1196708363, COSV99718082; called by muse, mutect2, varscan2
- PHOX2B | c.267C>T p.H89= | Silent (SNP) | VAF 62/234 reads (26%) | catalogued as rs749994532, COSV56929729; called by muse, mutect2, varscan2
- PIP | c.372T>G p.P124= | Silent (SNP) | VAF 110/277 reads (40%) | catalogued as COSV99344190; called by muse, mutect2, varscan2
- PLCE1 | c.2400G>A p.L800= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99595510; called by muse, varscan2
- POLR2A | c.4329C>T p.A1443= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs201531764; called by muse, mutect2, varscan2
- R3HDM1 | c.2011C>T p.L671= | Silent (SNP) | VAF 60/192 reads (31%) | catalogued as COSV99926390; called by muse, mutect2, varscan2
- RETREG1 | c.297C>T p.F99= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1246227310, COSV100104529; called by muse, mutect2, varscan2
- RPGRIP1L | c.3789C>T p.A1263= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV100046476; called by muse, mutect2, varscan2
- TRAF4 | c.630C>T p.H210= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99286502; called by muse, mutect2, varscan2
- ZNF529 | c.1365T>C p.C455= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs1280438177, COSV100485299; called by muse, mutect2
- DLG2 | c.205-65810C>T | Intron (SNP) | VAF 104/512 reads (20%) | catalogued as rs745933356, COSV99712122; called by muse, mutect2, varscan2
- DST | c.16635+343G>A | Intron (SNP) | VAF 83/320 reads (26%) | catalogued as COSV55028856; called by muse, mutect2, varscan2
- RIMS2 | c.4064-21178C>T | Intron (SNP) | VAF 6/34 reads (18%) | catalogued as COSV51659171, COSV51671487; called by muse, mutect2
- SNORD115-40 | n.12G>A | RNA (SNP) | VAF 170/565 reads (30%) | catalogued as rs1566756145; called by muse, mutect2
